Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADC2, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADC2-TTM1-A (Metastatic).

[page 1 of 13]
Patient Name:

Med. Rec. #:

DOB:

Gender:

F

Physician(s):

(Age: 82)

Client:

Location:

Billing #:

Copy To:

Accession #:

Collected:

Received:

Reported:

Final Pathologic Diagnosis

- A. SOFT TISSUE, PERITONEUM, BIOPSY AND FROZEN SECTION:
CARCINOMA, CONSISTENT WITH METASTASIS FROM PATIENT'S HIGH GRADE
PAPILLARY SEROUS CARCINOMA (SEE SPECIMEN B).
- B. BILATERAL OVARIES, OOPHORECTOMY AND FROZEN SECTION:
PAPILLARY SEROUS CARCINOMA, HIGH GRADE.
- C. SOFT TISSUE, DIAPHRAGM, BIOPSY:
METASTATIC HIGH GRADE CARCINOMA, CONSISTENT WITH METASTASIS FROM
PATIENT'S OVARIAN PRIMARY.
- D. OMENTUM, BIOPSY:
METASTATIC HIGH GRADE CARCINOMA, CONSISTENT WITH METASTASIS FROM
PATIENT'S KNOWN OVARIAN PRIMARY.

Comment

have reviewed the malignancy in part "B" and agree with the above diagnosis.

Intraoperative Consultation

- A. PERITONEAL BIOPSY:
ATYPICAL SURFACE IMPLANTS.
- B. LEFT AND RIGHT OVARIES, FROZEN SECTION:
ADENOCARCINOMA.

Clinical History

LARGE COMPLEX ADNEXAL MASS

[page 2 of 13]
SURGICAL PATHOLOGY CONSULTATION

Patient: [REDACTED]

Specimen: [REDACTED]

Specimen(s) Received

- A: PERITONEUM, BIOPSY
- B: BILATERAL OVARIES
- C: DIAPHRAGM, BIOPSY
- D: OMENTUM

Gross Description

- A. Labeled with the patient's name [REDACTED] and "peritoneal biopsy" are two irregular portions of yellow lobulated soft tissue measuring 0.4 x 0.7 cm in maximum dimension. The specimen is submitted in its entirety for frozen section. The frozen section residue is submitted for permanents.
- B. Labeled with the patient's name [REDACTED] and "left and right ovary" a 78 gram aggregate of irregular fragmented portions of tan to tan-pink to red shaggy to nodular firm soft tissues aggregating 10.5 x 7.0 x 2.0 cm. There are no obvious recognizable structures. The specimen is serially sectioned. Representative sections are submitted labeled [REDACTED] 8 blocks.
- C. Labeled with the patient's name [REDACTED] and "right diaphragm biopsy" are three fragmented portions of membranous tan-pink soft tissue, measuring 0.7 cm and 3.0 cm in greatest dimension. One surface is a smooth, glistening, tan-pink. The opposing surface contains multiple white bosselations averaging 0.3 cm in greatest dimension. The larger portion of tissue is bisected. [REDACTED] block.
- D. Labeled with the patient's name [REDACTED] and "omentum" is a 17.0 x 8.0 x 2.0 cm portion of lobulated yellow adipose tissue, consistent with omentum. There are multiple palpable firm white nodules throughout the specimen. Sectioning of the specimen reveals firm variegated yellow-white cut surfaces, revealing fat necrosis. The remainder of the specimen reveals lobulated yellow cut surfaces. The dense firm white tissue represents approximately 70% of the specimen. Representative sections are labeled [REDACTED] blocks.

Microscopic Description

A, C and D. Microscopic evaluation performed.

B. Sections of ovary demonstrate diffuse infiltration by a high grade neoplasm. The nuclei are moderate to markedly pleomorphic with enlarged, hyperchromatic nuclei, prominent nucleoli and atypical mitosis. The cells are arranged in plates and papilla. There is dense fibrosis surrounding the invasive papillary serous carcinoma.

ICD Codes: [REDACTED]

[page 3 of 13]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 84 Sex: F
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED]
Radiology No: [REDACTED]
Unit No: [REDACTED]

CAT SCAN

EXAM#	TYPE/EXAM	RESULT
-------	-----------	--------

[REDACTED]	CT/CT ABDOMEN W/CONTRAST	[REDACTED]
Reason for Exam: OVARIAN CA 6 MO FU		
Comment:		

Transportation? A - AMBULATORY
Clear Liquids Since? MIDNIGHT
Is Pt diabetic? N

[REDACTED]	CT/CT PELVIS W/CONTRAST	[REDACTED]
Reason for Exam: OVARIAN CA 6 MO FU		
Comment:		

Transportation? A - AMBULATORY
Clear Liquids Since? MIDNIGHT
Is Pt diabetic? N

Clinical data: Patient is an 84-year-old female with a history of ovarian cancer who complains of abdominal pain.

Technique: Serial axial 2.5 mm thick helically acquired CT images were performed from the dome of the liver to the symphysis pubis during rapid intravenous administration 75 mm of Visipaque 320 and after the patient had ingested radiographic contrast material for at least 2 hours prior to the examination. Coronal two-dimensional reformatted images were reconstructed from the data set. Rectal contrast was also administered.

Comparison examinations: Previous CT examination of the chest, abdomen, and pelvis on [REDACTED]

Findings:

Bones and soft tissues: Unremarkable.

Peritoneum: No peritoneal nodules are identified, there is no ascites.

Liver: The liver is of normal size and enhances normally, no focal hepatic lesion is identified.

Spleen: Normal.

Pancreas: Normal.

[page 4 of 13]
Name: [REDACTED]
Phys: [REDACTED] Age: 84 Sex: F
DOB: [REDACTED]
Acct: [REDACTED] Status: [REDACTED]
Exam Date: [REDACTED]
Radiology No: [REDACTED]
Unit No: [REDACTED]

CAT SCAN

EXAM#	TYPE/EXAM	RESULT
-------	-----------	--------

CT/CT ABDOMEN W/CONTRAST
Reason for Exam: OVARIAN CA 6 MO FU

Comment:

Transportation? A - AMBULATORY
Clear Liquids Since? MIDNIGHT
Is Pt diabetic? N

CT/CT PELVIS W/CONTRAST
Reason for Exam: OVARIAN CA 6 MO FU

Comment:

Transportation? A - AMBULATORY
Clear Liquids Since? MIDNIGHT
Is Pt diabetic? N

<Continued>

Gut and mesentery: Unremarkable in the abdomen, there are pancolonic colonic diverticula that are unchanged.

Adrenal glands: Normal.

Kidneys: There is normal late corticomedullary enhancement without evidence of mass or striation, there is no evidence of hydronephrosis or abnormal calcification.

Retroperitoneum: There is a small amount of atheromatous calcification in the aorta, no aneurysm is evident, and there is no retroperitoneal mass or lymphadenopathy identified.

Pelvis: The mucosa of the sigmoid colon is thickened in an area where there are multiple diverticula, but no paradiverticular extraluminal gas collections or fluid collection is identified and no pericolic fat stranding is evident. Patient is status post hysterectomy, no pelvic mass or lymphadenopathy is identified.

Caudal Thorax: Images through portions of the heart, lungs, mediastinum, diaphragm, and pleural surfaces reveal a small hiatus hernia, and no pulmonary nodules.

Impression:

- Findings of mild acute sigmoid diverticulitis.

[page 5 of 13]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 84 Sex: F
Acct: [REDACTED] Loc: CT
Exam Date: [REDACTED] Status: [REDACTED]
Radiology No: [REDACTED]
Unit No: [REDACTED]

CAT SCAN

EXAM#	TYPE/EXAM	RESULT
-------	-----------	--------

[REDACTED]	CT/CT ABDOMEN W/CONTRAST	[REDACTED]
Reason for Exam: OVARIAN CA 6 MO FU		
Comment:		
Transportation? A - AMBULATORY		
Clear Liquids Since? MIDNIGHT		
Is Pt diabetic? N		

[REDACTED]	CT/CT PELVIS W/CONTRAST	[REDACTED]
Reason for Exam: OVARIAN CA 6 MO FU		
Comment:		
Transportation? A - AMBULATORY		
Clear Liquids Since? MIDNIGHT		
Is Pt diabetic? N		
<Continued>		

2. No evidence of locally recurrent ovarian carcinoma, or regional or distant metastatic disease.
3. Small hiatus hernia.
4. Mild changes of atherosclerosis.
5. No change in findings of pancolonic diverticulosis.

** REPORT SIGNED IN OTHER VENDOR SYSTEM **

[REDACTED]

[page 6 of 13]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] age: 84 Sex: F
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED]
Radiology [REDACTED]
Unit No: [REDACTED]

CAT SCAN

EXAM#	TYPE/EXAM	RESULT
[REDACTED]	CT/CT ABDOMEN W/CONTRAST	[REDACTED]
[REDACTED]	CT/CT PELVIS W/CONTRAST	[REDACTED]

Clinical data: Patient is an 84-year-old female with a history of ovarian cancer who complains of abdominal pain.

Technique: Serial axial 2.5 mm thick helically acquired CT images were performed from the dome of the liver to the symphysis pubis during rapid intravenous administration 75 mm of Visipaque 320 and after the patient had ingested radiographic contrast material for at least 2 hours prior to the examination. Coronal two-dimensional reformatted images were reconstructed from the data set. Rectal contrast was also administered.

Comparison examinations: Previous CT examination of the chest, abdomen, and pelvis on [REDACTED] +357

Findings:

Bones and soft tissues: Unremarkable.

Peritoneum: No peritoneal nodules are identified, there is no ascites.

Liver: The liver is of normal size and enhances normally, no focal hepatic lesion is identified.

Spleen: Normal.

Pancreas: Normal.

Gut and mesentery: Unremarkable in the abdomen, there are pancolonic colonic diverticula that are unchanged.

Adrenal glands: Normal.

[page 7 of 13]
Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 84 Sex: F
Acct: [REDACTED]
Exam Date: [REDACTED] Status: [REDACTED]
Radiology NO: [REDACTED] +552
Unit No: [REDACTED]

CAT SCAN

EXAM#	TYPE/EXAM	RESULT
[REDACTED]	CT/CT ABDOMEN W/CONTRAST	[REDACTED]
[REDACTED]	CT/CT PELVIS W/CONTRAST	[REDACTED]

<Continued>

Kidneys: There is normal late corticomedullary enhancement without evidence of mass or striation, there is no evidence of hydronephrosis or abnormal calcification.

Retroperitoneum: There is a small amount of atheromatous calcification in the aorta, no aneurysm is evident, and there is no retroperitoneal mass or lymphadenopathy identified.

Pelvis: The mucosa of the sigmoid colon is thickened in an area where there are multiple diverticula, but no paradiverticular extraluminal gas collections or fluid collection is identified and no pericolic fat stranding is evident. Patient is status post hysterectomy, no pelvic mass or lymphadenopathy is identified.

Caudal Thorax: Images through portions of the heart, lungs, mediastinum, diaphragm, and pleural surfaces reveal a small hiatus hernia, and no pulmonary nodules.

Impression:

1. Findings of mild acute sigmoid diverticulitis.
2. No evidence of locally recurrent ovarian carcinoma, or regional or distant metastatic disease.
3. Small hiatus hernia.
4. Mild changes of atherosclerosis.

[page 8 of 13]
Patient:
DOB:
Site:
Ref. Prov:
Add. Prov:

EMPI:
PT:
Exam:
M.D.

Out

Visit/Acct:
MRN:
Room/Bed: /

EXAM DATE:

Contrast:

+932

PROCEDURE: PET-CT FUSION; TUMOR IMAGING, SKULL BASE TO MID-THIGH

INDICATIONS: Restage for possible recurrence of ovarian cancer. CA-125 has recently increased.

COMPARISON: None.

RADIOPHARMACEUTICAL: 15.26 millicuries F-18 FDG administered intravenously.

TECHNIQUE: The radiopharmaceutical was administered intravenously and the patient lay quietly in a recumbent position in a darkened room for 60 minutes; whole body attenuation-corrected images were performed from above the eyes to the mid-thighs; Non concurrent helically-acquired axial CT images were obtained for PET-CT fusion purposes. At time of FDG administration, the patient's blood-glucose level was 105.

FINDINGS:

NECK: There is a focus of markedly increased FDG activity within the medial aspect of the left supraclavicular fossa. This fuses to a moderately enlarged lymph node. The maximum SUV is 3.7. The features are of concern for a metastatic Virchow's lymph node. Consideration could be given to ultrasound of this region with potential ultrasound guided biopsy.

CHEST: No pathologic FDG activity or adenopathy.

ABDOMEN/PELVIS: No pathologic FDG activity or adenopathy. Small bilateral fat containing inguinal hernias are noted.

IMPRESSION: Small focus of markedly increased FDG activity fusing to a moderately enlarged left supraclavicular lymph node. Findings raise concern for a metastatic Virchow's lymph node.

No potential neoplastic uptake identified elsewhere.

[page 9 of 13]
Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Asst:

MRN:

Room/Bed:

EXAM DATE:

+1209

Contrast:

PROCEDURE: CHEST RADIOGRAPH, 2 VIEWS

COMPARISON: None.

INDICATIONS: Shortness of breath for two months getting worse

FINDINGS:

LUNGS: Lungs are hyperinflated consistent with COPD but are clear. No pulmonary masses or focal infiltrates.

CARDIAC: Heart size is upper limits of normal but not frankly enlarged. Bipolar pacemaker is noted with its wires intact.

MEDIASTINUM: Normal.

PLEURA: Normal.

BONES: Normal for age.

OTHER: Central venous catheter is seen with its tip projecting at the cavoatrial junction and with catheter port positioned over the left anterior chest wall. Pacemaker battery pack projects over the right upper chest wall.

CONCLUSION: COPD. Bipolar transvenous pacemaker. Central venous port. No acute cardiopulmonary disease.

[page 10 of 13]
Patient:

DOB:

Site:

Ref. Prov

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Acct:

MRN:

Room/Bed:

EXAM DATE:

Contrast/Isotope: 100cc Isovue 370

+2480

PROCEDURE: CT ABDOMEN AND PELVIS WITH INTRAVENOUS CONTRAST

COMPARISON: CT-ABDO/PELVIS-FOR COMPARISON +552

INDICATIONS: Abdominal pain with nausea, vomiting, diarrhea for 2 days. History of cancer of the vulva with vulvectomy and bilateral groin lymph node resection +2450

TECHNIQUE: CT scan of the abdomen and pelvis was performed with non-ionic intravenous contrast.

FINDINGS:

LUNG BASES:

Normal.

LIVER:

Few scattered tiny hepatic foci are unchanged and likely benign cysts.

BILIARY:

Normal.

PANCREAS:

Uneven lipomatosis of the pancreas seen as an anatomic variant.

SPLEEN:

Normal.

KIDNEYS:

Normal.

ADRENALS:

Normal.

AORTA/VASCULAR:

Mild atherosclerosis without aneurysmal dilatation.

RETROPERITONEUM:

Scattered nonenlarged retroperitoneal lymph nodes.

BOWEL/MESENTERY:

Diffuse mild colonic wall thickening and enhancement consistent with colitis. Minimal soft tissue stranding of the pericolonic fat. No free intraperitoneal fluid or air.

ABDOMINAL WALL:

Normal.

PELVIC ORGANS:

Post-operative changes status post hysterectomy.

BONES:

Normal for age.

OTHER:

Negative.

CONCLUSION: Diffuse colonic wall thickening and enhancement consistent with colitis. This is most likely infectious in etiology. Inflammatory bowel disease or ischemic colitis are considered less likely.

[page 11 of 13]
[REDACTED]

Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Exam:

MRN:

Room/Bed

EXAM DATE:

Contrast/Isotope:

+2442

PROCEDURE: CHEST RADIOGRAPH(S), 2 VIEWS, PA AND LATERAL

COMPARISON: [REDACTED] XR, XR CHEST 2 VIEWS PA AND LAT,
+1553

INDICATIONS: High blood pressure. Cancer. Upcoming surgery scheduled [REDACTED] +2450

FINDINGS:

LUNGS: Normal. No significant pulmonary parenchymal abnormalities.

CARDIAC: Right subclavian approach dual lead pacemaker is evident with leads unchanged in position.

MEDIASTINUM: Left subclavian approach Port-A-Cath with the tip terminating in the SVC.

PLEURA: Normal. No effusion or pleural thickening.

BONES: Normal. No fracture or visible bony lesion.

OTHER: Negative.

CONCLUSION: No acute disease. No evidence of distant metastatic disease.

[REDACTED]

[page 12 of 13]
Patient:
DOB:
Site:
Ref. Prov:
Add. Prov:

EMPI:
PT/MD:
Exam:

Visit/Acct:
MRN:
Room/Bed: /

EXAM DATE:

+1153

Contrast:

PROCEDURE: CHEST RADIOGRAPH. 2 VIEWS

COMPARISON:

XR, XR CHEST 1 VIEW AP OR PA.

+1528

INDICATIONS: Follow up on pneumonia, Pt feels better but is still coughing and is quite fatigued.

FINDINGS:

LUNGS: No acute airspace disease is evident. Faint subcentimeter nodule projected over the anterior aspect of the left fourth rib, nonspecific.

CARDIAC: Normal size cardiac silhouette. Right subclavian dual-lead pacemaker is unchanged.

MEDIASTINUM: Left subclavian Port-A-Cath terminates in the SVC.

PLEURA: Normal.

BONES: Normal for age.

OTHER: Negative.

CONCLUSION:

No acute airspace disease is evident.

Faint nodule projected over the anterior aspect of the left fourth rib is nonspecific.

[page 13 of 13]
Patient:
DOB:
Site:
Ref. Prov
Add. Pro

EMPI:
PT/MOD:
Exam:

Visit/Acct:
MRN:
Room/Bed

EXAM DATE:

+2485 Contrast/Isotope:

PROCEDURE: CHEST RADIOGRAPH(S), 2 VIEWS, PA AND LATERAL

+2442

COMPARISON: XR, XR CHEST 2 VIEWS PA AND LAT,

INDICATIONS: Shortness of breath.

CONCLUSION: Bibasilar reticular opacities could be atelectasis or pneumonitis. There bilateral pleural effusions. Heart size is normal, but there is moderate pulmonary venous distention. Findings could represent pneumonitis or heart failure.

Left subclavian port type catheter in right subclavian dual lead pacemaker remain in satisfactory position.

Source: NCI Genomic Data Commons file 9c2091d3-92a2-44dd-ad8d-3126933a19dd (ER0330 ER-ADC2 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).